National Lung Screening Trial (NLST) participant 209253 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 61 years; Gender: male; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 40 effective mAs, display field of view 34 cm, reconstruction filter Siemens B50F / Siemens B30.
- T1 (day 336): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 40 effective mAs, display field of view 31 cm, reconstruction filter Siemens B50F / Siemens B30.
- T2 (day 721): Positive, no significant change: stable abnormalities potentially related to lung cancer, unchanged since the prior screening exam. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 40 effective mAs, display field of view 31 cm, reconstruction filter Siemens B50F / Siemens B30.

Abnormalities recorded by the reading radiologist on the CT screens (21 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T0 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 4 mm, longest perpendicular diameter 3 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 44.
- T0 abnormality 3: Benign lung nodule(s) (benign calcification).
- T0 abnormality 4: Other minor abnormality noted.
- T0 abnormality 5: Other minor abnormality noted.
- T1 abnormality 1: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T1 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 8 mm, longest perpendicular diameter 7 mm; margins smooth; predominant attenuation mixed; greatest diameter on CT slice 50; pre-existing on earlier images (earliest visible day 0); no interval growth; suspicious interval change in attenuation.
- T1 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 4 mm, longest perpendicular diameter 3 mm; margins poorly defined; predominant attenuation ground glass; greatest diameter on CT slice 53; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T1 abnormality 4: Benign lung nodule(s) (benign calcification).
- T1 abnormality 5: Emphysema; pre-existing on earlier images (earliest visible day 0); interval change does not warrant further investigation.
- T1 abnormality 6: Other minor abnormality noted.
- T1 abnormality 7: Other minor abnormality noted.
- T1 abnormality 8: Other minor abnormality noted.
- T2 abnormality 1: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 4 mm, longest perpendicular diameter 3 mm; margins smooth; predominant attenuation ground glass; greatest diameter on CT slice 51; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T2 abnormality 3: Benign lung nodule(s) (benign calcification).
- T2 abnormality 4: Emphysema; pre-existing on earlier images (earliest visible day 0); interval change does not warrant further investigation.
- T2 abnormality 5: Other minor abnormality noted.
- T2 abnormality 6: Other minor abnormality noted.
- T2 abnormality 7: Other minor abnormality noted.
- T2 abnormality 8: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 8 mm, longest perpendicular diameter 7 mm; margins smooth; predominant attenuation ground glass; greatest diameter on CT slice 48; identified only on comparison with prior images.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,333.
